Surgical pathology report (de-identified scan), TCGA case TCGA-UW-A72T, project TCGA-KICH (Kidney Chromophobe), tissue source site University of North Carolina, specimen TCGA-UW-A72T-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY

Case Number :

ICD-O-3
Carcinoma, renal cell
chromophobe type
8/17/13
Site @ Kidney NOS
164.9
JW 8/9/13

Diagnosis:

A: Kidney, right, laparoscopic right radical nephrectomy

Procedure: laparoscopic radical nephrectomy

Laterality: right

Histologic tumor type/subtype: Renal cell carcinoma, chromophobe type, eosinophilic variant

Immunostains/special stains show the following results:

- BER EP4: positive
- CD117: negative
- CD15: negative
- RCC: negative
- CK7: strongly positive
- E-Cadherin: strongly positive
- Colloidal iron: positive

Sarcomatoid features: not identified

Histologic grade (if applicable): 3

Tumor size (greatest dimension): 8.7 cm

Tumor focality: unifocal

Extent of tumor invasion (if present specify if macroscopic or microscopic):

Capsular invasion/perirenal adipose tissue: not identified

Gerota' s fascia: uninvolved with tumor

Renal sinus: tumor invades into renal sinus adipose tissue

Major veins (renal vein or segmental branches, IVC): free of tumor

Ureter: free of tumor

Venous (large vessel): not identified

Lymphatic (small vessel): not identified

Histologic assessment of surgical margins:

Gerota' s fascia (nephrectomy): margins uninvolved with tumor

Renal vein (nephrectomy): margins uninvolved with tumor

Ureter (nephrectomy): margins uninvolved with tumor

[page 2 of 4]
Adrenal gland: not present in specimen

Lymph nodes: none present in specimen

Pathologic findings in non-neoplastic kidney: none

AJCC Staging:

pT3a

pNx

This staging information is based on information available at the time of this report, and is subject to change pending clinical review and additional information.

Comment:

We note that the core biopsy of this tumor was interpreted as renal oncocytoma. This excision specimen has much more tissue to examine, and shows the eosinophilic variant of chromophobe carcinoma. This variant of chromophobe carcinoma has granular, eosinophilic tumor cells without the punched out nuclear halos of usual chromophobe carcinoma. Eosinophilic variant of chromophobe carcinoma may look very similar to oncocytoma in a small sample. The immunostains and the colloidal iron results on this excision specimen are very typical of chromophobe carcinoma, with the exception of the negative CD117. The entire immunostain/colloidal iron profile along with the morphology strongly supports the interpretation of chromophobe carcinoma. The tumor involves the renal sinus adipose tissue. Grossly, the tumor extended into the perinephric fat, but microscopically the bulge into the perinephric tissues is covered by renal capsule, so capsular invasion is not identified.

Clinical History:

-year-old male with NKDA, right renal mass.

Gross Description:

Received is one appropriately labeled container, additionally labeled "right kidney".

Specimen fixation: Formalin

Type of specimen: Radical right nephrectomy

[page 3 of 4]
Side of specimen: Right

Size and weight of specimen: Nephrectomy is 955 grams (24.0 x 10.7 x 6.7 cm); kidney 11.7 x 6.7 x 4.0 cm)

Orientation: Inking: perinephric fat/blue

Presence/absence of adrenal gland: Absent

Tumor site: Renal cortex/medulla at the lower pole and extends to the mid portion of the kidney and into the hilum.

Tumor description: Tumor is a solid soft mahogany brown, circumscribed with focal lobulated borders. Approximately 30% of the mass is necrotic.
Hemorrhage is absent.

Tumor size: 8.7 x 6.6 x 5.2 cm

Presence/absence of multicentricity: Absent

Confinement/non-confinement to the kidney: Mass is not confined, extends into the hilum, through the capsule and into the perinephric fat.

Extent of invasion:

Perirenal adipose tissue: Tumor grossly involves

Gerota' s fascia: Does not involve

Renal vein: Does not involve

Ureter: Does not involve

Renal Sinus: Grossly involves

Pelvicaliceal: Does not involve

Adrenal: N/A

Other organs: N/A

Surgical margins:

Perirenal adipose tissue: Negative, is 0.2 cm from the perirenal adipose tissue margin

[page 4 of 4]
Renal vein: Negative

Renal artery: Negative

Ureter: Negative

Description of kidney away from tumor: The parenchyma is red/brown with a well-demarcated cortex medulla. The tumor compresses and displaces the renal pelvis. The renal pelvis lining is pink/tan and smooth.

Hilar lymph nodes: No

Other significant findings: At the superior pole is a 0.7 x 0.5 cm ovoid area of smooth gray cortical discoloration. This discoloration is 3.3 cm from the mass.

Tissue submitted for
are given to

Tumor and normal

Digital picture: No

Block Summary:

- A1 - Renal vein, renal artery and ureter margins, en face
- A2 - Mass with renal sinus
- A3-A5 - Perpendicular of mass at the hilum
- A6-A7 - Mass closest to the perirenal adipose tissue margin
- A8 - Mass with renal pelvis
- A9-10 - Additional sections of mass
- A11 - Superior pole cortical discoloration

*Proximal Hodgkin lymphoma with
NO treatment. BCR*

Source: NCI Genomic Data Commons file 2a0c2cfa-1a18-4123-8f03-457992814db0 (TCGA-UW-A72T.737E2F94-3DDD-4D44-8FCD-F82B443C038A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).